Somatic mutation profile of tumor specimen TCGA-B6-A0X1-01A (aliquot TCGA-B6-A0X1-01A-11D-A10G-09) from TCGA case TCGA-B6-A0X1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 48.3 years (17,624 days).
Specimen TCGA-B6-A0X1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14743e3f-6964-420d-87cf-887e08bf4bf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0X1-10A (Blood Derived Normal), aliquot TCGA-B6-A0X1-10A-01D-A117-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bda15891-5533-4cc7-8bb3-dde23376f014

The open-access MAF lists 80 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 13, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 3, Intron 3, In Frame Del 2, RNA 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 73/123 reads (59%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- UROS | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 76/109 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs121908015, CM920704, COSV64223332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV100382886; called by muse, mutect2
- ABHD2 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV61772640; called by muse, mutect2, varscan2
- AKAP11 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV50292403; called by muse, mutect2, varscan2
- AKNAD1 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV62194387; called by muse, mutect2, varscan2
- ARAP3 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53348235; called by muse, mutect2, varscan2
- ATP12A | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs200347989, COSV54511681; called by muse, mutect2, varscan2
- ATP4B | c.758T>G p.I253S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.258); catalogued as COSV58928445; called by muse, mutect2, varscan2
- ATXN7L2 | c.704A>G p.K235R | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.526); catalogued as rs1370911598, COSV63992027; called by muse, mutect2, varscan2
- BID | c.608_619del p.K203_A206del (on ENST00000317361 / NM_197966.2; = p.K157_A160del on NM_001196.4) | In Frame Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs759487323; called by mutect2, pindel, varscan2
- CACNA2D2 | c.3007G>A p.E1003K (on ENST00000479441 / NM_001174051.3; = p.E996K on NM_006030.4) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.311); catalogued as COSV56559929; called by muse, mutect2, varscan2
- CAD | c.2371G>C p.D791H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV53023098; called by muse, mutect2, varscan2
- CARF | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV57546026; called by muse, mutect2, varscan2
- CCDC80 | c.120G>T p.L40F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.055); catalogued as COSV52814694; called by muse, mutect2, varscan2
- COPG1 | c.425G>C p.R142P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59112129; called by muse, mutect2, varscan2
- CYB5R1 | c.896A>T p.Q299L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV61850750; called by muse, mutect2, varscan2
- CYP39A1 | c.645G>C p.W215C | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99242082; called by muse, mutect2
- CYP3A4 | c.611T>G p.V204G | Missense Mutation (SNP) | VAF 88/268 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV60500838; called by muse, mutect2, varscan2
- DPP4 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 128/229 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62104648; called by muse, mutect2, varscan2
- EPHB3 | c.1946G>C p.R649P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57803907; called by muse, mutect2, varscan2
- F13B | c.1354+1G>A p.X452_splice | Splice Site (SNP) | VAF 12/132 reads (9%) | catalogued as COSV100803249; called by muse, mutect2
- FCRL5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs890785912, COSV62510933; called by muse, mutect2, varscan2
- FOXB2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65022338; called by muse, mutect2
- GPT2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as rs367834055; called by muse, mutect2, varscan2
- GRIN2A | c.1407_1408insT p.T470Yfs*21 | Frame Shift Ins (INS) | VAF 23/120 reads (19%) | catalogued as COSV58018151; called by mutect2, pindel, varscan2
- HK3 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs543207235, COSV52836543; called by muse, mutect2, varscan2
- KAT6B | c.1384T>C p.Y462H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.77); catalogued as COSV99767693; called by muse, mutect2
- MDN1 | c.10519C>T p.R3507C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1425483459, COSV65516301; called by muse, mutect2, varscan2
- MRAS | c.399G>C p.L133F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV56669936; called by muse, mutect2
- MTF1 | c.2135T>G p.L712* | Nonsense Mutation (SNP) | VAF 7/118 reads (6%) | catalogued as COSV100888611; called by muse, mutect2
- MYLK | c.5398G>A p.V1800I | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV60603651; called by muse, mutect2, varscan2
- NSMCE4A | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 144/384 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.381); catalogued as COSV64632509, COSV64632711; called by muse, mutect2, varscan2
- OR5AK2 | c.59del p.Q20Rfs*17 | Frame Shift Del (DEL) | VAF 72/182 reads (40%) | catalogued as COSV58803618; called by mutect2, pindel*, varscan2
- OR8B2 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66664096; called by muse, mutect2, varscan2
- OSBP2 | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV60239072; called by muse, mutect2, varscan2
- PCDHB12 | c.107T>C p.M36T | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV53392632; called by muse, mutect2, varscan2
- PGM2L1 | c.784C>A p.H262N | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53344891; called by muse, mutect2, varscan2
- PLIN2 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99438808; called by muse, mutect2
- PRB4 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); catalogued as COSV54395409, COSV99686440; called by muse, mutect2
- PRKX | c.178T>G p.F60V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53321784; called by muse, mutect2
- RBM41 | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV52561855; called by muse, mutect2, varscan2
- RCN1 | c.539T>A p.L180H | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); catalogued as COSV50014230; called by muse, mutect2, varscan2
- REV3L | c.7634G>C p.R2545T | Missense Mutation (SNP) | VAF 5/132 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100725063; called by muse, mutect2
- RIOX2 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as rs373581249; called by muse, mutect2, varscan2
- SCFD2 | c.1314C>T p.S438= | Splice Region (SNP) | VAF 33/109 reads (30%) | catalogued as COSV66368230; called by muse, mutect2, varscan2
- SNAPC3 | c.784A>G p.K262E | Missense Mutation (SNP) | VAF 118/286 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.082); catalogued as rs753910525, COSV66402551; called by muse, mutect2, varscan2
- TBC1D23 | c.1666G>C p.D556H (on ENST00000394144 / NM_001199198.3; = p.D541H on NM_018309.5) | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100792519, COSV61368715; called by muse, mutect2
- TLE2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs750568962, COSV53578070; called by muse, mutect2, varscan2
- TMEM67 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100018935; called by muse, mutect2
- TRIM67 | c.1989C>G p.H663Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV64157999; called by muse, mutect2, varscan2
- UNC5D | c.2041G>T p.E681* | Nonsense Mutation (SNP) | VAF 91/121 reads (75%) | catalogued as COSV54765541; called by muse, mutect2, varscan2
- WDR45 | c.1019A>G p.D340G (on ENST00000376372 / NM_001029896.2; = p.D341G on NM_007075.3) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV59875379; called by muse, mutect2, varscan2
- XPO6 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 53/119 reads (45%) | catalogued as COSV58962922; called by muse, mutect2, varscan2
- ZNF345 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as rs149256110, COSV59323502; called by muse, mutect2, varscan2
- ZNF625 | c.874T>C p.Y292H | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.926); catalogued as COSV100863460; called by muse, mutect2
- BRCA1 | c.67del p.E23Sfs*8 | Frame Shift Del (DEL) | VAF 147/254 reads (58%) | called by mutect2, pindel, varscan2
- DMRTC1 | c.511C>G p.R171G | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DST | c.14965_14984delinsA p.E4989Tfs*3 (on ENST00000361203 / NM_001374722.1; = p.E2577Tfs*3 on NM_015548.5) | Frame Shift Del (DEL) | VAF 39/196 reads (20%) | called by pindel, varscan2*
- HSPA6 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.497); called by muse, mutect2
- TLR7 | c.1039_1053del p.L347_F351del | In Frame Del (DEL) | VAF 22/128 reads (17%) | called by mutect2, pindel, varscan2
- TRPA1 | c.1906-7_1919del p.X636_splice | Splice Site (DEL) | VAF 53/181 reads (29%) | called by mutect2, pindel, varscan2
- USP43 | c.1203_1204del p.F402Lfs*2 | Frame Shift Del (DEL) | VAF 46/100 reads (46%) | called by pindel, varscan2
- ABCB1 | c.1191T>C p.V397= | Silent (SNP) | VAF 9/209 reads (4%) | catalogued as COSV99712585; called by muse, mutect2
- ARPIN | c.321C>T p.D107= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs753540224, COSV62589783; called by muse, mutect2, varscan2
- GPATCH8 | c.3000C>T p.S1000= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as COSV59192909; called by muse, mutect2, varscan2
- ITIH2 | c.1110T>G p.V370= | Silent (SNP) | VAF 46/184 reads (25%) | catalogued as COSV64431740; called by muse, mutect2, varscan2
- NME7 | c.717T>C p.C239= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV100890969; called by muse, mutect2
- OSMR | c.309C>G p.L103= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs773759068, COSV57080359, COSV57087619; called by muse, mutect2, varscan2
- POLR2C | c.450C>T p.I150= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs781607112, COSV54671591; called by muse, mutect2, varscan2
- RSPH10B2 | c.1567C>T p.L523= | Silent (SNP) | VAF 127/191 reads (66%) | catalogued as COSV51867392; called by muse, mutect2, varscan2
- SAMD9 | c.3468A>T p.A1156= | Silent (SNP) | VAF 17/279 reads (6%) | catalogued as COSV101180170; called by muse, mutect2
- SEC14L5 | c.237C>T p.V79= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV52035913; called by muse, mutect2, varscan2
- TFAP2B | c.364C>T p.L122= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99539890; called by muse, mutect2
- TM6SF2 | c.846G>T p.L282= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV52268231; called by muse, mutect2, varscan2
- TMC3 | c.2619G>C p.S873= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs201930890, COSV63922001; called by muse, mutect2, varscan2
- CALCR | c.52-3326A>C | Intron (SNP) | VAF 61/134 reads (46%) | catalogued as COSV64005389; called by muse, mutect2, varscan2
- MASP1 | c.1303+5467T>A | Intron (SNP) | VAF 8/31 reads (26%) | catalogued as COSV56220598; called by muse, mutect2, varscan2
- TP73-AS1 | n.1227C>G | RNA (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.10360+4006T>C | Intron (SNP) | VAF 51/116 reads (44%) | catalogued as COSV59861382; called by muse, mutect2, varscan2
